Somatic mutation profile of tumor specimen HCM-WCMC-0749-C34-01A (aliquot HCM-WCMC-0749-C34-01A-20D-A87L-36) from HCMI case HCM-WCMC-0749-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Bronchio-alveolar carcinoma, mucinous; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 72.6 years (26,530 days).
Specimen HCM-WCMC-0749-C34-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6dfef36b-fe6c-4c53-b5e0-e88d83536dfb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0749-C34-10A (Blood Derived Normal), aliquot HCM-WCMC-0749-C34-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2808644-d5b8-4504-a3df-5a784096a48f

The open-access MAF lists 64 somatic variants for this specimen: 54 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 8, Nonsense Mutation 4, Frame Shift Del 2, Intron 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 62/406 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 43/398 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057520000, COSV52677206, COSV52707835, COSV52811105; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACOX3 | c.1927G>A p.V643M | Missense Mutation (SNP) | VAF 39/371 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs771510910, COSV62712160; called by muse, mutect2, varscan2
- ACTL9 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 38/375 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs782721280, COSV61006019; called by muse, mutect2, varscan2
- ARSB | c.1212G>A p.P404= | Splice Region (SNP) | VAF 38/357 reads (11%) | catalogued as rs143071401; called by muse, mutect2, varscan2
- BRINP2 | c.1905G>T p.W635C | Missense Mutation (SNP) | VAF 32/412 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64181003; called by muse, mutect2
- C11orf87 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 53/398 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as rs746570507; called by muse, mutect2, varscan2
- CILP2 | c.2123G>A p.R708H | Missense Mutation (SNP) | VAF 43/320 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs775642324; called by muse, mutect2, varscan2
- DCAF12L1 | c.630C>A p.S210R | Missense Mutation (SNP) | VAF 134/378 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100948382, COSV64422747; called by muse, mutect2, varscan2
- EPHA5 | c.2539C>T p.P847S | Missense Mutation (SNP) | VAF 75/447 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56630335; called by muse, mutect2, varscan2
- GABRA4 | c.1045del p.E349Kfs*36 | Frame Shift Del (DEL) | VAF 69/621 reads (11%) | catalogued as COSV51927022; called by mutect2, varscan2
- HPRT1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 106/352 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV100053104; called by muse, mutect2, varscan2
- JAK1 | c.2679G>T p.R893S | Missense Mutation (SNP) | VAF 73/536 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs778030565; called by muse, mutect2, varscan2
- KRTAP1-1 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 42/388 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs772154453; called by muse, mutect2
- LRP1B | c.13610C>T p.A4537V | Missense Mutation (SNP) | VAF 81/599 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.939); catalogued as rs376526778, COSV67255727; called by muse, mutect2, varscan2
- MYT1 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 87/456 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1262501301, COSV100114942; called by muse, mutect2, varscan2
- NKX2-1 | c.522C>G p.Y174* | Nonsense Mutation (SNP) | VAF 42/364 reads (12%) | catalogued as CD1310890, CM146073; called by muse, mutect2, varscan2
- NKX2-1 | c.204C>A p.Y68* | Nonsense Mutation (SNP) | VAF 44/287 reads (15%) | catalogued as CM120082; called by muse, mutect2, varscan2
- OR14J1 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 36/628 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV65845587; called by muse, mutect2
- OR2T1 | c.368T>A p.V123E | Missense Mutation (SNP) | VAF 93/872 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV100822261; called by muse, mutect2, varscan2
- OR56B4 | c.428C>A p.T143N | Missense Mutation (SNP) | VAF 61/477 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1262031547; called by muse, mutect2, varscan2
- OXTR | c.1079C>T p.T360M | Missense Mutation (SNP) | VAF 48/369 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs199856198; called by muse, mutect2, varscan2
- RTKN2 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 45/427 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1256537620; called by muse, mutect2, varscan2
- SDK1 | c.6551C>A p.P2184Q | Missense Mutation (SNP) | VAF 53/359 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs762533739; called by mutect2, varscan2
- TTN | c.79963G>C p.D26655H (on ENST00000591111; = p.D19231H on NM_003319.4) | Missense Mutation (SNP) | VAF 55/647 reads (9%) | PolyPhen probably damaging (0.971); catalogued as COSV60327541; called by muse, mutect2
- UBN2 | c.1129G>A p.G377S | Missense Mutation (SNP) | VAF 70/564 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs368430654; called by muse, mutect2, varscan2
- UNC13B | c.4298C>G p.P1433R | Missense Mutation (SNP) | VAF 27/296 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100266718, COSV100266773; called by muse, mutect2
- WWC1 | c.1628C>G p.P543R | Missense Mutation (SNP) | VAF 86/487 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.89); catalogued as rs751993520; called by muse, mutect2, varscan2
- ZNF804A | c.3526G>A p.V1176I | Missense Mutation (SNP) | VAF 66/712 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs767120954, COSV56442498, COSV56462276; called by muse, mutect2
- ZNF99 | c.2299G>C p.G767R | Missense Mutation (SNP) | VAF 41/406 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101233779; called by muse, mutect2, varscan2
- ATR | c.6619T>A p.S2207T | Missense Mutation (SNP) | VAF 38/396 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.744); called by muse, mutect2
- BMPER | c.1605C>A p.N535K | Missense Mutation (SNP) | VAF 72/518 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CCNE1 | c.1222G>T p.E408* | Nonsense Mutation (SNP) | VAF 50/438 reads (11%) | called by muse, mutect2
- CX3CL1 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 50/312 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- DACH1 | c.1214del p.P405Lfs*30 | Frame Shift Del (DEL) | VAF 71/635 reads (11%) | called by mutect2, varscan2
- DDB1 | c.3092G>T p.G1031V | Missense Mutation (SNP) | VAF 48/309 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM104A | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- HEATR5B | c.2506G>T p.G836C | Missense Mutation (SNP) | VAF 21/247 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.927); called by muse, mutect2
- IGFL4 | c.257C>A p.T86K | Missense Mutation (SNP) | VAF 46/387 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KCNB2 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 53/419 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- MAGEL2 | c.2014G>T p.G672C | Missense Mutation (SNP) | VAF 61/436 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MS4A3 | c.146A>T p.Q49L | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- PCDHGA1 | c.1482C>A p.D494E | Missense Mutation (SNP) | VAF 38/485 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.072); called by muse, mutect2
- PDE4D | c.1933C>T p.Q645* (on ENST00000340635 / NM_001104631.2; = p.Q509* on NM_006203.4) | Nonsense Mutation (SNP) | VAF 65/601 reads (11%) | called by muse, mutect2, varscan2
- PLPPR4 | c.343C>A p.P115T | Missense Mutation (SNP) | VAF 77/615 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PPP1R3A | c.1130G>A p.S377N | Missense Mutation (SNP) | VAF 54/477 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PRR32 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 128/376 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- SELL | c.575C>A p.T192N (on ENST00000650983; = p.T179N on NM_000655.5) | Missense Mutation (SNP) | VAF 109/501 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC27A6 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 44/339 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SOD3 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.293); called by muse, varscan2
- SP8 | c.839T>A p.M280K (on ENST00000361443 / NM_198956.4; = p.M298K on NM_182700.6) | Missense Mutation (SNP) | VAF 54/404 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.117); called by mutect2, varscan2
- SPTA1 | c.6324G>T p.Q2108H | Missense Mutation (SNP) | VAF 70/823 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- TAX1BP1 | c.1704A>C p.E568D | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); called by muse, mutect2
- UBA6 | c.710A>T p.H237L | Missense Mutation (SNP) | VAF 40/349 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ABCA13 | c.5043G>A p.Q1681= | Silent (SNP) | VAF 65/511 reads (13%) | called by muse, mutect2, varscan2
- ARHGEF40 | c.4290C>T p.A1430= | Silent (SNP) | VAF 56/518 reads (11%) | catalogued as rs1354383756; called by muse, mutect2, varscan2
- COG7 | c.1311C>T p.T437= | Silent (SNP) | VAF 45/381 reads (12%) | called by muse, mutect2, varscan2
- DDX3Y | c.1663T>C p.L555= | Silent (SNP) | VAF 48/206 reads (23%) | called by muse, mutect2, varscan2
- FSCB | c.1113A>T p.P371= | Silent (SNP) | VAF 78/651 reads (12%) | called by muse, mutect2, varscan2
- RNF169 | c.486C>T p.A162= | Silent (SNP) | VAF 20/164 reads (12%) | catalogued as rs777876455; called by muse, mutect2, varscan2
- RYR2 | c.12189G>A p.T4063= | Silent (SNP) | VAF 70/641 reads (11%) | catalogued as rs368948386; called by muse, mutect2, varscan2
- STARD9 | c.573T>C p.H191= | Silent (SNP) | VAF 19/185 reads (10%) | called by muse, mutect2, varscan2
- CCDC158 | c.1029+3605C>T | Intron (SNP) | VAF 46/385 reads (12%) | called by muse, mutect2, varscan2
- CEP89 | c.39+286C>T | Intron (SNP) | VAF 51/408 reads (13%) | catalogued as rs1016700301; called by muse, mutect2, varscan2
